Surgical pathology report (de-identified scan), TCGA case TCGA-06-5413, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-5413-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

[REDACTED]

Surgical Pathology Report

TCGA-06-5413

=====

CLINICAL HISTORY
Brain tumor.

OPERATIVE DIAGNOSES

Operation/Specimen: A: Brain, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A. Brain, tumor, excision biopsy: High-grade glioma consistent with glioblastoma (WHO grade IV) (see comment).

COMMENT

The frozen section diagnosis is confirmed on permanent sections. The sections

show a high-grade glial neoplasm with mitotic activity and extensive necrosis.

Immunostaining of the lesion shows GFAP positivity, keratin negativity and a Ki-67 labeling index of approximately 20 percent. Positive and negative controls are reviewed and appropriate immunoreactivity is confirmed.

[REDACTED]

INTRA-OPERATIVE CONSULTATION

A. Brain, excision biopsy: High-grade glioma consistent with glioblastoma. Frozen section and smears performed at [REDACTED] and results reported to the Physician of Record. [REDACTED]

[REDACTED]

[page 2 of 2]
GROSS DESCRIPTION

A. Brain, excision biopsy: CONTAINER LABEL: brain tumor

FIXATIVE: fresh

GENERAL: Received is a 12 x10 x2mm pink-tan fragment. Touch prep and frozen section performed.

SECTIONS: 1-frozen section remnant, 2-remaining tissue, [REDACTED]
mid, [REDACTED]

[REDACTED]

ICD-9(s):

191.9 191.9

[REDACTED]

The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These were developed and their performance characteristics determined by the Immunohistochemistry Laboratory in the Department of Pathology, [REDACTED]. They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes, it should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] (CLIA) as qualified to perform high complexity clinical laboratory testing.

Histo Data

Part A: Brain, excision biopsy

Taken: [REDACTED]	Received: [REDACTED]		
Stain/cnt	Block	Ordered	Comment
FS H/E x 1	1	[REDACTED]	
mGFAP-DA x 1	1	[REDACTED]	
H/E x 1	1	[REDACTED]	
KeratinSu x 1	1	[REDACTED]	
MIB1-DA x 1	1	[REDACTED]	
TPS H/E x 1	1	[REDACTED]	
mGFAP-DA x 1	2	[REDACTED]	
H/E x 1	2	[REDACTED]	
KeratinSu x 1	2	[REDACTED]	
MIB1-DA x 1	2	[REDACTED]	

*** End of Report ***

Source: NCI Genomic Data Commons file 32314c9b-b9f5-4f44-b6ba-721f5b569a7e (TCGA-06-5413.81757237-A9C0-49AD-AC5A-68601083BE40.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).